Somatic mutation profile of cancer-model specimen HCM-CSHL-0186-C25-85A (3D Organoid; aliquot HCM-CSHL-0186-C25-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0186-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 74.2 years (27,102 days).
Specimen HCM-CSHL-0186-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 227af9c5-45b0-4a6e-9358-85a037cf501b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0186-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0186-C25-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e3feb72-8abf-4bdf-974b-eb2009bf7c98

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 14, Frame Shift Ins 2, 5'UTR 1, Translation Start Site 1, Nonsense Mutation 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 136/277 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 194/195 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- CARMIL3 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 136/362 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.153); catalogued as rs142826860; called by muse, mutect2, varscan2
- CCDC166 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 308/828 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.16); catalogued as rs1199782513; called by muse, mutect2, varscan2
- CDKN2A | c.130dup p.Y44Lfs*76 | Frame Shift Ins (INS) | VAF 187/265 reads (71%) | catalogued as COSV58682773, COSV58689669, COSV58711803, COSV58713131; called by mutect2, pindel, varscan2
- CHAF1A | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 229/466 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as rs150699024; called by muse, mutect2, varscan2
- DNM1 | c.1346A>G p.Y449C | Missense Mutation (SNP) | VAF 146/366 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1329661423; called by muse, varscan2
- EPB42 | c.89G>A p.R30H (on ENST00000441366 / NM_001114134.2; = p.R60H on NM_000119.3) | Missense Mutation (SNP) | VAF 186/442 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs1329445100, COSV55751390; called by muse, mutect2, varscan2
- FAM47A | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.923); catalogued as COSV60495629; called by muse, mutect2
- FOXG1 | c.1008C>G p.S336R | Missense Mutation (SNP) | VAF 265/545 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.188); catalogued as COSV57399167; called by muse, mutect2, varscan2
- HS3ST2 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 228/448 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564701428, COSV54457820; called by muse, mutect2, varscan2
- LRRC38 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 57/441 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs573361035; called by muse, mutect2, varscan2
- MVP | c.1972G>A p.V658I | Missense Mutation (SNP) | VAF 258/492 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs986124471, COSV62423538; called by muse, mutect2, varscan2
- PAPPA2 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV62772131; called by muse, mutect2, varscan2
- PLA2G4D | c.2432C>T p.A811V | Missense Mutation (SNP) | VAF 150/288 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs370314190; called by muse, mutect2, varscan2
- PLK5 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 333/686 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs943611813; called by muse, mutect2, varscan2
- PTP4A1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs755475012; called by muse, mutect2, varscan2
- RET | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 142/288 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs149238501, COSV60688566, COSV60711451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOT2 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 206/852 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); catalogued as rs983443032; called by muse, mutect2, varscan2
- RND2 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 122/388 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1182099592, COSV56816512; called by muse, mutect2, varscan2
- SCN5A | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs199473559, CM100637, COSV61118815; ClinVar: not provided; called by muse, mutect2, varscan2
- SLITRK3 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 39/610 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1219260576, COSV99578283; called by muse, mutect2
- SMAD4 | c.140T>C p.L47P | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61688293, COSV99048762; called by muse, mutect2
- TTC31 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 70/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1308285567, COSV52036228; called by muse, mutect2, varscan2
- ZFP64 | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 166/437 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as rs1568679651, COSV53800118; called by muse, mutect2, varscan2
- ATP2B1 | c.1197del p.Q400Rfs*18 | Frame Shift Del (DEL) | VAF 217/300 reads (72%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.2850T>A p.F950L | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BARHL2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 322/733 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- C11orf54 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 112/268 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- CLOCK | c.2075dup p.T693Nfs*35 | Frame Shift Ins (INS) | VAF 97/328 reads (30%) | called by mutect2, pindel, varscan2
- EPHA10 | c.1923T>A p.D641E | Missense Mutation (SNP) | VAF 113/368 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- KCNJ15 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 170/360 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- KDM6A | c.3840T>A p.N1280K | Missense Mutation (SNP) | VAF 137/137 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MMRN2 | c.778A>T p.R260* | Nonsense Mutation (SNP) | VAF 180/352 reads (51%) | called by muse, mutect2, varscan2
- NDUFB8 | c.91C>G p.H31D | Missense Mutation (SNP) | VAF 155/293 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- OR13C5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 22/313 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- PAPOLA | c.65_94del p.I22_P31del | In Frame Del (DEL) | VAF 101/287 reads (35%) | called by mutect2, pindel, varscan2
- SCAF8 | c.3088C>A p.P1030T | Missense Mutation (SNP) | VAF 142/304 reads (47%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.018); called by muse, varscan2
- SDHAF2 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 160/352 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHANK3 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 82/320 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPEG | c.7681C>G p.P2561A | Missense Mutation (SNP) | VAF 299/574 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TMEM248 | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 32/488 reads (7%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.953); called by muse, mutect2
- VWA5B2 | c.3536G>T p.R1179L | Missense Mutation (SNP) | VAF 294/819 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- ZBED5 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 31/374 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.705); called by muse, mutect2
- ADCY5 | c.3147C>T p.A1049= | Silent (SNP) | VAF 357/572 reads (62%) | catalogued as rs754369625, COSV59194567; called by muse, mutect2, varscan2
- CRAMP1 | c.2181G>A p.Q727= | Silent (SNP) | VAF 42/764 reads (5%) | catalogued as rs774178478; called by muse, mutect2
- GRM8 | c.2136C>T p.V712= | Silent (SNP) | VAF 117/305 reads (38%) | called by muse, mutect2, varscan2
- MAPK12 | c.933C>T p.F311= | Silent (SNP) | VAF 40/326 reads (12%) | catalogued as rs1240740383, COSV53136118, COSV99299327; called by muse, mutect2, varscan2
- NDUFAF6 | c.90C>T p.Y30= | Silent (SNP) | VAF 339/689 reads (49%) | called by muse, mutect2, varscan2
- OR11L1 | c.297A>C p.A99= | Silent (SNP) | VAF 128/365 reads (35%) | called by muse, mutect2
- PCDHA9 | c.1869C>T p.R623= | Silent (SNP) | VAF 17/512 reads (3%) | catalogued as COSV100970209; called by muse, mutect2
- SHANK1 | c.5190C>G p.A1730= | Silent (SNP) | VAF 209/506 reads (41%) | called by muse, mutect2, varscan2
- SMC2 | c.3593A>G p.*1198= | Silent (SNP) | VAF 75/140 reads (54%) | called by muse, mutect2, varscan2
- SMPD4 | c.1398G>A p.S466= (on ENST00000409031 / NM_017951.4; = p.S437= on NM_017751.4) | Silent (SNP) | VAF 185/433 reads (43%) | catalogued as rs1558742121, COSV60079749; called by muse, mutect2, varscan2
- TMCC1 | c.1354C>T p.L452= (on ENST00000393238 / NM_001349268.2; = p.L128= on NM_015008.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 107/472 reads (23%) | catalogued as rs774568800; called by muse, mutect2, varscan2
- USH2A | c.8643A>T p.S2881= | Silent (SNP) | VAF 102/222 reads (46%) | called by muse, mutect2, varscan2
- XPR1 | c.330C>T p.R110= | Silent (SNP) | VAF 103/294 reads (35%) | catalogued as rs1394123540, COSV62561654; called by muse, mutect2, varscan2
- ZNF608 | c.3075G>A p.T1025= | Silent (SNP) | VAF 26/302 reads (9%) | catalogued as rs746665494; called by muse, mutect2
- PREP | c.-115C>T | 5'UTR (SNP) | VAF 102/260 reads (39%) | catalogued as rs766719326; called by muse, mutect2, varscan2
